Somatic mutation profile of tumor specimen TCGA-VQ-A927-01A (aliquot TCGA-VQ-A927-01A-12D-A410-08) from TCGA case TCGA-VQ-A927, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 81.2 years (29,676 days).
Specimen TCGA-VQ-A927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95e17c91-1d3f-4d61-8620-506c08c181f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A927-10A (Blood Derived Normal), aliquot TCGA-VQ-A927-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0ab6d14-bb9d-4308-a069-3bdf93478090

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG3 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100342039; called by muse, mutect2, varscan2
- CACNA1C | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100214963, COSV59772971; called by muse, mutect2
- CASS4 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100824519, COSV64386967; called by muse, mutect2
- CES4A | c.24C>A p.S8R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.808); catalogued as COSV100109925; called by muse, mutect2
- CFAP57 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs542413771, COSV100993887, COSV65265474; called by muse, mutect2
- CTNNA3 | c.2013A>C p.E671D | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.76); catalogued as COSV101041233; called by muse, mutect2, varscan2
- DHX34 | c.3232C>A p.L1078I | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100169209; called by muse, mutect2
- DYRK3 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV100895591; called by muse, mutect2
- ECT2L | c.983T>G p.L328R | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.942); catalogued as COSV100871745; called by muse, mutect2
- EYS | c.896T>A p.V299D | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100675619; called by muse, mutect2
- FER | c.1127A>G p.K376R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99811456, COSV99812524; called by muse, mutect2
- FGF6 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762919183, COSV99960129; called by muse, mutect2
- HS1BP3 | c.415T>A p.S139T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV100397759; called by muse, mutect2
- HS3ST4 | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100499953; called by muse, mutect2
- LCE2B | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.095); catalogued as COSV100909277; called by muse, mutect2
- LRP1B | c.1385A>T p.Y462F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV101251777; called by muse, mutect2, varscan2
- MAGEC1 | c.1396A>C p.T466P | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.403); catalogued as COSV99594771; called by muse, mutect2, varscan2
- NYAP1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | catalogued as COSV55723198; called by muse, mutect2
- OVGP1 | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs140775603; called by muse, mutect2, varscan2
- PCDHA8 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1203215461, COSV100970412, COSV65337237; called by muse, mutect2
- PCDHB16 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.294); catalogued as rs138310875; called by muse, mutect2
- PDE3A | c.2076G>T p.W692C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100761614, COSV62971380; called by muse, mutect2
- PLAAT1 | c.532G>A p.D178N (on ENST00000650797; = p.D73N on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs765880194, COSV99290513; called by muse, mutect2
- SCML2 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV52617993; called by muse, mutect2
- SH3PXD2B | c.157A>T p.M53L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100287632; called by muse, mutect2
- SYNCRIP | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV100783978; called by muse, mutect2
- TTC26 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.785); catalogued as COSV100570860; called by muse, mutect2
- TTN | c.61894T>G p.L20632V (on ENST00000591111; = p.L13208V on NM_003319.4) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | PolyPhen benign (0.017); catalogued as COSV100592699; called by muse, mutect2
- USP14 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as rs1489731148, COSV99863784; called by muse, mutect2
- KPNB1 | c.848G>C p.W283S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP16 | c.401del p.V134Gfs*31 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ZNF606 | c.1950dup p.P651Tfs*3 | Frame Shift Ins (INS) | VAF 10/100 reads (10%) | called by mutect2, pindel
- ACAP3 | c.624G>A p.L208= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV100686004; called by muse, mutect2
- APOB | c.6963T>C p.V2321= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as COSV99263371; called by muse, mutect2
- ELP1 | c.3258A>G p.G1086= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV101010320; called by muse, mutect2
- GPR146 | c.783G>A p.S261= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs201455933, COSV52466239; called by muse, mutect2, varscan2
- LRRK1 | c.3238A>C p.R1080= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV99437330; called by muse, mutect2
- MED28 | c.364T>C p.L122= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99403601; called by muse, mutect2, varscan2
- STK3 | c.528A>G p.A176= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as rs1463930710, COSV101372433; called by muse, mutect2
- THBS3 | c.2070A>G p.S690= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100857452; called by muse, mutect2
- ZC3H7A | c.2379T>G p.A793= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV100865440; called by muse, mutect2
- LBP | c.*1G>A | 3'UTR (SNP) | VAF 16/292 reads (5%) | catalogued as rs912701463, COSV99460336; called by muse, mutect2
- SNORD114-24 | n.17G>A | RNA (SNP) | VAF 9/118 reads (8%) | catalogued as rs1318496319; called by muse, mutect2
